Surgical pathology report (de-identified scan), TCGA case TCGA-HD-7229, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-7229-01A (Primary Tumor).

[page 1 of 2]
Surg Path Final Report

* Final Report *

Result Type:
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

* Final Report *

Final Diagnosis (Verified)

Left supraglottic mass, biopsy with OR consultation:

Invasive moderate to poorly differentiated squamous cell carcinoma.

Broad foci of tumor are present at the cauterized biopsy margins.

Left thyroid cartilage, biopsy with frozen section:

Invasive moderate to poorly differentiated squamous cell carcinoma.

Left supraglottic tumor, biopsy:

Invasive moderate to poorly differentiated squamous cell carcinoma.

Comment: Selected material also reviewed by

Operating Room Consultation (Verified)

A – Left supraglottic mass,

Printed by:
Printed on:

[page 2 of 2]
Surg Path Final Report

* Final Report *

ORCA-A: 3 fragments of soft tissue measuring 2.5 x 2 x 0.8 cm in aggregate of.
Portion of the specimen was given to [REDACTED] for research project.

Frozen Section Diagnosis (Verified)

B – Left thyroid cartilage, FS:

FS-B: Invasive squamous cell carcinoma. [REDACTED]

Clinical Information (Verified)

Heart disease, CABG, cancer.

Gross Description (Verified)

"ORCA." The specimen consists of 3 fragments of soft tissue measuring 2.5 x 2.0 x 0.8 cm in aggregate. These fragments are sectioned and submitted in cassettes "A1," and "A2," all.

"FSB." All frozen section control tissue is submitted in cassette "FSB."

"C, Left supraglottic cancer." The specimen consists of 2.5 x 1.0 x 0.5 cm aggregate of gray-white to red-brown rubbery tissue. "C," fragments, all. [REDACTED]

Signature Line

[REDACTED]

Completed Action List:

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 172d9e81-fe3c-443c-9eb3-2868fc980d6d (TCGA-HD-7229.5A33B240-07A7-4BBD-8A0B-15F106BA183E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).